Gene-level copy-number profile of tumor specimen TCGA-CV-5443-01A from TCGA case TCGA-CV-5443, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.8 years (23,287 days).
Specimen TCGA-CV-5443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d85d8a17-8aea-49d3-8a03-8f13141c163b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5443-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/acdadf75-12d4-4c97-b770-e3a2db792c37

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 2: 7,866; copy number 3: 33; copy number 4: 51,213; copy number 5: 42; copy number 6: 397; copy number 7: 103; copy number 9: 22; copy number 13: 67; copy number 19: 59; copy number 102: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5443-01A-01D-1510-01): tumor purity 0.58, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:102,922,663–103,149,408, 12 genes: AMN, CDC42BPB, AL117209.1, RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12.
- chr16:56,961,923–57,083,531, 4 genes (within-gene range 0–2): CETP, NLRC5, AC023825.1, AC023825.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 149 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:5,357,971–5,470,566, 3 genes, copy number 13–102 (within-gene range 6–102): PLGRKT, RNF152P1, CD274.
- chr20:31,356,870–35,278,131, 146 genes, copy number 9–19 (within-gene range 5–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
